Somatic mutation profile of tumor specimen TCGA-D3-A8GN-06A (aliquot TCGA-D3-A8GN-06A-11D-A372-08) from TCGA case TCGA-D3-A8GN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 30.9 years (11,296 days).
Specimen TCGA-D3-A8GN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 165d2572-6723-4025-9c5a-3e8e6164c345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GN-10A (Blood Derived Normal), aliquot TCGA-D3-A8GN-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f6cda05-81d9-459e-812f-68cc098bf2a9

The open-access MAF lists 293 somatic variants for this specimen: 169 protein-altering or splice-affecting, 114 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 114, Nonsense Mutation 7, Intron 4, RNA 4, 3'UTR 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB1 | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774299788, COSV55958979; called by muse, mutect2, varscan2
- AC097636.1 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101469694; called by muse, mutect2, varscan2
- ACTR6 | c.429A>C p.L143F | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.9); catalogued as COSV99498779; called by muse, mutect2, varscan2
- ADAM2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs1486484687, COSV55858669; called by muse, mutect2, varscan2
- ADGRB2 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99926919; called by muse, mutect2, varscan2
- ADGRL2 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV54652364; called by muse, mutect2, varscan2
- ALMS1 | c.11735C>T p.P3912L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100043758; called by muse, mutect2
- AMOT | c.2141C>T p.S714F (on ENST00000371959 / NM_001113490.1; = p.S305F on NM_133265.3) | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495561; called by muse, mutect2
- ARHGAP30 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs759817018, COSV63519294; called by muse, mutect2
- ATAD2B | c.3895G>A p.G1299R | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV99478476; called by muse, mutect2
- C12orf42 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.693); catalogued as COSV100172855; called by muse, mutect2, varscan2
- C2orf16 | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.136); catalogued as COSV68843029; called by muse, mutect2
- C8A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777495880, COSV63483150; called by muse, mutect2, varscan2
- CATSPERD | c.1902G>A p.M634I | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58464338; called by muse, mutect2
- CBFA2T2 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs376557268; called by muse, mutect2, varscan2
- CCDC171 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs760537450, COSV99901984; called by muse, mutect2, varscan2
- CCDC191 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290396756, COSV99878771; called by muse, mutect2, varscan2
- CCND3 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs889367305, COSV100882243; called by muse, mutect2, varscan2
- CD36 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757331847, COSV99987887; called by muse, mutect2, varscan2
- CDH26 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99722988; called by muse, mutect2, varscan2
- CDH6 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99420849; called by muse, mutect2
- CDKL5 | c.1780T>C p.Y594H | Missense Mutation (SNP) | VAF 9/277 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as COSV101184455; called by muse, mutect2
- CFAP69 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290121; called by muse, mutect2, varscan2
- CNGB1 | c.3310G>A p.G1104S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV99211250; called by muse, mutect2, varscan2
- CNTRL | c.365A>G p.E122G | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs1457125519, COSV53047442; called by muse, mutect2, varscan2
- COG7 | c.2054T>G p.I685S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100207822; called by muse, mutect2, varscan2
- COL1A1 | c.3472C>T p.L1158F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.448); catalogued as rs1567753373, COSV99868164; called by muse, mutect2
- COL4A4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100307728; called by muse, mutect2, varscan2
- CPXM2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751380071, COSV53872919; called by muse, mutect2, varscan2
- CRACD | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as rs780145063, COSV99950019; called by muse, mutect2, varscan2
- CREG2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV61316088; called by muse, mutect2, varscan2
- CSMD1 | c.8462G>A p.G2821E (on ENST00000520002; = p.G2820E on NM_033225.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1185114228, COSV100153615; called by mutect2, varscan2
- CTNNA2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs745947461, COSV63552800; called by muse, mutect2, varscan2
- CWH43 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.269); catalogued as COSV56937070; called by muse, mutect2, varscan2
- CYP4X1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs964059939, COSV100903356; called by muse, mutect2, varscan2
- DCAF12 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.295); catalogued as COSV100778411; called by muse, mutect2, varscan2
- DCAF12L1 | c.1196G>A p.R399K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1290316029, COSV100948447; called by muse, mutect2, varscan2
- DCAF8L1 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs749330123, COSV101491545; called by muse, mutect2, varscan2
- DCANP1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV72345817; called by muse, mutect2, varscan2
- DEPDC5 | c.2474C>T p.S825F (on ENST00000400246; = p.S894F on NM_014662.5) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV99836576; called by muse, mutect2, varscan2
- DNAH8 | c.7376G>A p.G2459E | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547243; called by muse, mutect2, varscan2
- DNAH9 | c.4732G>A p.D1578N | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1186330478, COSV52333468; called by muse, mutect2, varscan2
- DOCK11 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV99354746; called by muse, mutect2, varscan2
- DOCK4 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs1274938541, COSV101447984; called by muse, mutect2, varscan2
- DSG3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774736138, COSV57124224; called by muse, mutect2, varscan2
- DUOX2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100545973; called by muse, mutect2, varscan2
- EML5 | c.3525G>T p.W1175C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764142945, COSV100716195; called by muse, mutect2, varscan2
- ENPP6 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99699144; called by muse, mutect2, varscan2
- EPS8L3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100719756; called by muse, mutect2, varscan2
- ERI3 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1341440730, COSV100952266; called by muse, mutect2, varscan2
- FAM171A1 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968564; called by muse, mutect2, varscan2
- FAM47A | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV60494452; called by muse, mutect2
- FAM47A | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100650087, COSV60500071; called by muse, mutect2
- FAM47B | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1216086473, COSV100264456; called by muse, mutect2, varscan2
- FAM71B | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs911745462, COSV57229782, COSV57230751; called by muse, mutect2, varscan2
- FAT4 | c.8543C>T p.S2848F | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV100630211; called by muse, mutect2, varscan2
- FGD3 | c.1788G>A p.K596= | Splice Region (SNP) | VAF 31/133 reads (23%) | catalogued as COSV100490898; called by muse, mutect2, varscan2
- FGL1 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768389622, COSV101112508; called by muse, mutect2, varscan2
- FLG2 | c.5045G>A p.G1682E | Missense Mutation (SNP) | VAF 168/423 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as rs771163168, COSV101165572, COSV101166224; called by muse, mutect2, varscan2
- FOLR3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100281868; called by muse, mutect2, varscan2
- GABRA3 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772835335, COSV64803103; called by muse, mutect2, varscan2
- GIMAP2 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56235471; called by muse, mutect2, varscan2
- GPC6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65500845; called by muse, mutect2, varscan2
- GUCY1A2 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV99976922; called by muse, mutect2, varscan2
- HECW1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101224305; called by muse, mutect2, varscan2
- HMCN1 | c.9724C>T p.Q3242* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV54911046, COSV99635830; called by muse, mutect2
- HTR1E | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs777916050, COSV59507236; called by muse, mutect2, varscan2
- ITSN1 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.926); catalogued as COSV101180625; called by muse, mutect2, varscan2
- JAKMIP1 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1313972918, COSV51539800; called by muse, mutect2, varscan2
- JCAD | c.3887C>T p.A1296V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100948575; called by muse, mutect2, varscan2
- KALRN | c.6362G>A p.G2121E (on ENST00000360013 / NM_001024660.4; = p.G424E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1216557962, COSV99362980; called by muse, mutect2
- KCNA4 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV100069275; called by muse, mutect2
- KCNH4 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99236944, COSV99237799; called by muse, mutect2, varscan2
- KCNH6 | c.898C>T p.L300F | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100121267, COSV59002501; called by muse, mutect2, varscan2
- KCNT2 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as rs1327032306, COSV99656748; called by muse, mutect2
- KCTD5 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746098413, COSV100069443, COSV100069710; called by muse, mutect2
- KIF21A | c.2608G>A p.E870K (on ENST00000361418 / NM_001378440.1; = p.E857K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.069); catalogued as rs373609055; called by muse, mutect2, varscan2
- KIR2DL4 | c.644G>A p.G215E (on ENST00000396284; = p.G176E on NM_001080770.2) | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1569362607; called by muse, mutect2, varscan2
- KRT20 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753435426, COSV99391600; called by muse, mutect2, varscan2
- LINGO2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs371555423; called by muse, mutect2, varscan2
- LRFN2 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824808; called by muse, mutect2, varscan2
- LRP1B | c.5305G>T p.V1769L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV101261080; called by muse, mutect2
- MACROH2A2 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100952373; called by muse, mutect2, varscan2
- MAGEC2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV55997927, COSV55998505; called by muse, mutect2
- MAGI2 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100832741, COSV100836603; called by muse, mutect2
- MAPK7 | c.1045A>T p.K349* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100219093; called by muse, mutect2, varscan2
- MFN1 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs1468417112, COSV99764708; called by muse, mutect2, varscan2
- MGAM | c.3815C>T p.P1272L | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101527754; called by muse, mutect2, varscan2
- MMGT1 | c.133-1G>T p.X45_splice | Splice Site (SNP) | VAF 10/165 reads (6%) | catalogued as COSV100018742; called by muse, mutect2
- MORC4 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.679); catalogued as rs1465053937, COSV55247256, COSV99717627; called by muse, mutect2, varscan2
- MPND | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV99515379; called by muse, mutect2
- MRPL10 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as rs1243152687, COSV99270533; called by muse, mutect2, varscan2
- MUC16 | c.34913C>T p.S11638F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.42); catalogued as COSV101201731; called by muse, mutect2, varscan2
- MUC16 | c.12184C>T p.L4062F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV67451136; called by muse, mutect2
- MYH13 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs773432205, COSV52828927; called by muse, mutect2, varscan2
- NBAS | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs373721233, COSV99870893; called by muse, mutect2, varscan2
- NCAM1 | c.1323T>A p.Y441* (on ENST00000316851 / NM_181351.5; = p.Y431* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100378223; called by muse, mutect2, varscan2
- NCBP1 | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.035); catalogued as rs563951596, COSV100910655; called by muse, mutect2, varscan2
- NEB | c.10651C>T p.H3551Y | Missense Mutation (SNP) | VAF 97/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51460793, COSV99428042; called by muse, mutect2, varscan2
- NLRP5 | c.2101C>T p.R701C | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs368914781, COSV66762342; called by muse, mutect2, varscan2
- NPAP1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as COSV100276202; called by muse, mutect2, varscan2
- NTRK3 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.49); catalogued as rs1313486936, COSV100713888; called by muse, mutect2, varscan2
- NUP205 | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV99607610; called by muse, mutect2, varscan2
- OBSCN | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV99484332; called by muse, mutect2, varscan2
- OLR1 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100376440; called by muse, mutect2, varscan2
- OR12D3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs566487315, COSV101011473; called by muse, mutect2, varscan2
- OR2G3 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV60683150; called by muse, mutect2
- OR5A1 | c.714G>A p.W238* | Nonsense Mutation (SNP) | VAF 35/167 reads (21%) | catalogued as COSV100118474; called by muse, mutect2, varscan2
- OR5H6 | c.912G>A p.M304I (on ENST00000642105; = p.M288I on NM_001005479.2) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV101051740, COSV67351799; called by muse, mutect2, varscan2
- PAPPA2 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV62797896; called by muse, mutect2, varscan2
- PCDH15 | c.2386G>A p.V796I | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as rs374715306; called by muse, mutect2, varscan2
- PCDH18 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV100787522, COSV61270183; called by muse, mutect2, varscan2
- PCDHB13 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV53401241; called by muse, mutect2, varscan2
- PCLO | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.088); catalogued as COSV61640377; called by muse, mutect2, varscan2
- PEX5L | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs746551798, COSV55838512, COSV55857769; called by muse, mutect2, varscan2
- PKHD1L1 | c.4718C>T p.P1573L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs777495136, COSV101005533; called by muse, mutect2, varscan2
- PKM | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs752256480, COSV100065243; called by muse, mutect2, varscan2
- PLG | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1261821465, COSV51987988; called by muse, mutect2, varscan2
- POF1B | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53137868; called by muse, mutect2
- POM121 | c.3128C>T p.T1043M (on ENST00000434423; = p.T778M on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as rs782210412, COSV99988099; called by muse, mutect2, varscan2
- PPP1R17 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100566481; called by muse, mutect2, varscan2
- PRAMEF2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.327); catalogued as COSV99535713; called by muse, mutect2, varscan2
- PRLR | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1360228280, COSV99184778; called by muse, mutect2, varscan2
- PROSER2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs775619900, COSV53205348; called by muse, mutect2, varscan2
- PRPH2 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs758924894, COSV57838281; called by muse, mutect2, varscan2
- PRUNE2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65041958; called by muse, mutect2, varscan2
- RAPGEF3 | c.1819G>T p.A607S (on ENST00000389212; = p.A565S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1172988528, COSV50203020; called by muse, mutect2
- RB1CC1 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs770511277, COSV50244169, COSV50279290; called by muse, mutect2, varscan2
- RCE1 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1319449020, COSV100547189; called by muse, mutect2, varscan2
- RENBP | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as COSV100128511; called by muse, mutect2
- RSF1 | c.560C>A p.S187* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100407972; called by muse, mutect2, varscan2
- SAG | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101300707; called by muse, mutect2
- SERPINI1 | c.249T>G p.N83K | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.084); catalogued as COSV99855430; called by muse, mutect2, varscan2
- SLC6A18 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57254378; called by muse, mutect2, varscan2
- SLITRK6 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV101233299; called by muse, mutect2, varscan2
- SNAP91 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs762551616, COSV99536634; called by muse, mutect2, varscan2
- SNX20 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100319331; called by muse, mutect2, varscan2
- SNX29 | c.1938T>G p.S646R | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100030169; called by muse, mutect2, varscan2
- SRPK1 | c.1435C>T p.L479F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV100644460, COSV60415061; called by muse, mutect2
- SUPT6H | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.216); catalogued as rs1324243156, COSV99973082; called by muse, mutect2, varscan2
- SYT10 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57338434; called by muse, mutect2, varscan2
- TACC2 | c.5998C>A p.P2000T (on ENST00000334433; = p.P78T on NM_006997.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as COSV99587768; called by muse, mutect2, varscan2
- TAFA2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69172543; called by muse, mutect2, varscan2
- TARS3 | c.2323C>T p.H775Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs776166192, COSV60108578; called by muse, mutect2, varscan2
- TAS2R40 | c.921G>A p.W307* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV101283029, COSV101283032; called by muse, mutect2, varscan2
- TFAP2D | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50411327, COSV99147671; called by muse, mutect2
- THOC2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99834186; called by muse, mutect2
- TM6SF2 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.251); catalogued as rs1488530469, COSV99364039; called by muse, mutect2, varscan2
- TMEM45A | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.438); catalogued as COSV100058681; called by muse, mutect2, varscan2
- TMPO | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs1490180210, COSV58460771; called by muse, mutect2, varscan2
- TNIP3 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99284830; called by muse, mutect2, varscan2
- TNNI3K | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58548961; called by muse, mutect2, varscan2
- TOP2B | c.199C>T p.R67C (on ENST00000264331 / NM_001330700.2; = p.R62C on NM_001068.3) | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51968957; called by muse, mutect2, varscan2
- TRERF1 | c.419T>C p.L140S | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100551691; called by muse, mutect2, varscan2
- TRPA1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51573464; called by muse, mutect2, varscan2
- TRRAP | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs147405090, COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TTC21B | c.3157C>T p.R1053C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs776196183, COSV54628365; called by muse, mutect2, varscan2
- TTN | c.15794G>A p.R5265K (on ENST00000591111; = p.R4338K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/243 reads (28%) | PolyPhen benign (0.318); catalogued as COSV100630244; called by muse, mutect2, varscan2
- USP11 | c.466G>A p.V156M (on ENST00000218348; = p.V113M on NM_001371072.1) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV99511175; called by muse, mutect2
- USP15 | c.2642C>T p.S881F (on ENST00000280377 / NM_001351159.2; = p.S852F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740640; called by muse, mutect2, varscan2
- VAT1L | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746719665, COSV100214151; called by muse, mutect2, varscan2
- VWF | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99780168; called by muse, mutect2, varscan2
- ZBED9 | c.2932G>A p.G978R | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101509395; called by muse, mutect2, varscan2
- ZBTB14 | c.8T>C p.F3S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100813500; called by muse, mutect2, varscan2
- ZFHX4 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.103); catalogued as rs923379132, COSV50678515; called by muse, mutect2, varscan2
- ZNF398 | c.1613C>T p.P538L (on ENST00000475153 / NM_170686.3; = p.P367L on NM_020781.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100247058; called by muse, mutect2, varscan2
- ZNF676 | c.578G>A p.R193K (on ENST00000650058; = p.R161K on NM_001001411.3) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV101236221, COSV68093191; called by muse, mutect2, varscan2
- ZNRF3 | c.2167C>T p.P723S (on ENST00000544604 / NM_001206998.2; = p.P623S on NM_032173.3) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV100238996; called by muse, mutect2
- ACSM2B | c.1005C>T p.L335= | Silent (SNP) | VAF 47/231 reads (20%) | catalogued as rs539762138, COSV100313147, COSV61659980; called by muse, mutect2, varscan2
- ADAMTS10 | c.447C>T p.I149= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs782556409, COSV54353780; called by muse, mutect2, varscan2
- ADAMTS18 | c.1755C>T p.P585= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as COSV99274239; called by muse, mutect2, varscan2
- ADAMTS19 | c.2511C>T p.L837= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as rs150663560; called by muse, mutect2, varscan2
- AGXT | c.111C>T p.I37= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100280377; called by muse, mutect2
- AGXT2 | c.174C>T p.Y58= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV99183938; called by muse, mutect2, varscan2
- AL121899.2 | c.219G>A p.L73= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs776212414, COSV101198687; called by muse, mutect2, varscan2
- ANKRD11 | c.2863C>T p.L955= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs1188726211, COSV99970628; called by muse, mutect2, varscan2
- ANO2 | c.762G>A p.R254= (on ENST00000356134 / NM_001278597.3; = p.R258= on NM_001278596.3) | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV59021233, COSV59041646; called by muse, mutect2, varscan2
- AOC1 | c.48G>T p.T16= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100710999; called by muse, mutect2, varscan2
- APOBR | c.2835C>T p.A945= (on ENST00000431282; = p.A954= on NM_018690.4) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs373671373; called by muse, mutect2, varscan2
- ARHGDIA | c.579G>A p.E193= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV99482638; called by muse, mutect2, varscan2
- ATP1A1 | c.246C>T p.P82= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99814786; called by muse, mutect2, varscan2
- BDKRB1 | c.189C>T p.L63= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs768209755, COSV53705849; called by muse, mutect2, varscan2
- C1orf105 | c.456C>T p.F152= | Silent (SNP) | VAF 27/357 reads (8%) | catalogued as COSV100877984; called by muse, mutect2
- CACNA2D4 | c.1989G>A p.G663= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1301926830, COSV54962016; called by muse, mutect2, varscan2
- CDH8 | c.1644G>A p.K548= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs1257508404, COSV100184438, COSV54861232; called by muse, mutect2, varscan2
- CFH | c.459G>A p.E153= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs1182234991, COSV100661643; called by muse, mutect2, varscan2
- CFHR3 | c.342C>T p.C114= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs763700926, COSV100807780; called by muse, mutect2, varscan2
- CHDH | c.1230C>T p.H410= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs370185031; called by muse, mutect2, varscan2
- CLEC3A | c.612C>T p.I204= (on ENST00000651443; = p.I195= on NM_005752.6) | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55221658; called by muse, mutect2, varscan2
- CMIP | c.534C>T p.V178= (on ENST00000537098 / NM_198390.2; = p.V84= on NM_030629.3) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs761706969, COSV101220964; called by muse, mutect2, varscan2
- CNGA2 | c.252C>T p.F84= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100323956; called by muse, mutect2, varscan2
- COL1A1 | c.1809C>T p.P603= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56807049; called by muse, mutect2, varscan2
- CSMD1 | c.10062C>T p.F3354= (on ENST00000520002; = p.F3353= on NM_033225.6) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs376160512; called by muse, mutect2
- CSMD2 | c.7635G>A p.K2545= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV53882911; called by muse, mutect2, varscan2
- DCLK3 | c.1374C>T p.I458= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV69364686; called by muse, mutect2, varscan2
- DCST1 | c.1263G>A p.R421= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV99793652; called by muse, mutect2, varscan2
- DDOST | c.1164C>T p.F388= (on ENST00000415136; = p.F371= on NM_005216.5) | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as COSV100387423; called by muse, mutect2, varscan2
- DPYSL5 | c.111G>A p.Q37= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV99982802; called by muse, mutect2, varscan2
- DTX1 | c.129C>T p.T43= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs769437286, COSV57500579; called by muse, mutect2, varscan2
- ECPAS | c.1008C>T p.L336= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99399321; called by muse, mutect2, varscan2
- ELF4 | c.1389C>T p.F463= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100257597; called by muse, mutect2
- ERCC6L | c.492C>T p.F164= | Silent (SNP) | VAF 17/161 reads (11%) | catalogued as COSV100559263; called by muse, mutect2, varscan2
- FAM237A | c.444C>T p.F148= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs775710717, COSV71513309; called by muse, mutect2
- GABRB2 | c.762C>T p.I254= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as rs1372377153, COSV50909317; called by muse, mutect2, varscan2
- GDF3 | c.591T>C p.N197= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100325395, COSV61714001; called by muse, mutect2, varscan2
- H1-5 | c.228G>A p.V76= | Silent (SNP) | VAF 74/285 reads (26%) | catalogued as rs781695711, COSV58901177; called by muse, mutect2, varscan2
- HABP2 | c.1440C>T p.R480= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100668099; called by muse, mutect2, varscan2
- HECW1 | c.4506G>A p.R1502= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV67826432; called by muse, mutect2
- HIVEP3 | c.3453C>T p.L1151= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs1207391900, COSV56025272; called by muse, mutect2, varscan2
- HTR4 | c.702C>T p.A234= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs745999248, COSV100089678; called by mutect2, varscan2
- IDO1 | c.1089G>A p.K363= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99503236; called by muse, mutect2, varscan2
- IP6K3 | c.1056C>T p.A352= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as COSV53388936, COSV99540174; called by muse, mutect2, varscan2
- IRS1 | c.258C>T p.L86= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100524965; called by muse, mutect2
- IRX6 | c.195C>T p.G65= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs753210884, COSV51859680, COSV99306650; called by muse, mutect2, varscan2
- JADE3 | c.2061C>T p.F687= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV54467399, COSV99510302; called by muse, mutect2, varscan2
- KCNH6 | c.897C>T p.P299= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as rs1438804012, COSV100121266; called by muse, mutect2, varscan2
- KCNS2 | c.561G>A p.R187= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV99751470; called by muse, mutect2
- KEL | c.1143C>T p.F381= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV62333372; called by muse, mutect2, varscan2
- KIF2B | c.1113G>A p.K371= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV52127405; called by muse, mutect2, varscan2
- KLHL13 | c.654C>T p.F218= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as rs1021687832, COSV53249845; called by muse, mutect2
- KRT2 | c.1407G>A p.V469= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100548658; called by muse, mutect2, varscan2
- LACC1 | c.1233C>T p.S411= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100354802; called by muse, mutect2, varscan2
- LILRB1 | c.1185G>A p.K395= (on ENST00000427581; = p.K359= on NM_006669.6) | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as COSV100207898; called by muse, mutect2, varscan2
- MAGEE2 | c.537C>T p.L179= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100973213; called by muse, mutect2, varscan2
- MAP3K10 | c.258C>T p.G86= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1388560572, COSV99454862; called by muse, mutect2, varscan2
- MAP3K21 | c.2982C>T p.S994= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100786167; called by muse, mutect2, varscan2
- MATN3 | c.1227G>A p.G409= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV101337476; called by muse, mutect2, varscan2
- MPRIP | c.2307C>T p.I769= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100506131; called by muse, mutect2
- MYH6 | c.141C>A p.V47= | Silent (SNP) | VAF 30/326 reads (9%) | catalogued as COSV62452650; called by muse, mutect2
- NAALAD2 | c.1884C>T p.N628= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as COSV100428829; called by muse, mutect2, varscan2
- NEIL1 | c.295C>T p.L99= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1156673222, COSV61833135; called by muse, mutect2, varscan2
- NF1 | c.5472C>T p.I1824= (on ENST00000358273 / NM_001042492.3; = p.I1803= on NM_000267.3) | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV62211231; called by muse, mutect2, varscan2
- NLRP5 | c.120C>T p.F40= | Silent (SNP) | VAF 34/130 reads (26%) | catalogued as rs369527947; called by muse, mutect2, varscan2
- NPC1L1 | c.3783C>T p.L1261= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV56930942; called by muse, mutect2, varscan2
- NYAP1 | c.567G>A p.G189= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as rs1049369264, COSV55719293, COSV55719741; called by muse, mutect2, varscan2
- OR14K1 | c.690G>A p.Q230= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99315493; called by muse, mutect2, varscan2
- OR1F1 | c.315C>T p.F105= | Silent (SNP) | VAF 37/170 reads (22%) | catalogued as COSV100484509; called by muse, mutect2, varscan2
- OR5B12 | c.645C>T p.S215= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs753614012, COSV100222570; called by muse, mutect2, varscan2
- OR6N1 | c.858C>T p.N286= | Silent (SNP) | VAF 21/214 reads (10%) | catalogued as COSV58648940, COSV58649658; called by muse, mutect2
- OR6Q1 | c.723C>T p.A241= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV100110543; called by muse, mutect2, varscan2
- OR8D2 | c.600C>T p.F200= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs147744869, COSV100659111; called by muse, mutect2, varscan2
- PALLD | c.1824G>A p.R608= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99825842; called by muse, mutect2, varscan2
- PIK3C2A | c.3588C>T p.I1196= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99791208, COSV99791427; called by muse, mutect2, varscan2
- PPP1R14C | c.497G>A p.*166= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100745293; called by muse, mutect2, varscan2
- PRPF31 | c.705C>G p.A235= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs587627263, COSV100320126; called by muse, mutect2, varscan2
- PSG11 | c.180G>A p.Q60= | Silent (SNP) | VAF 53/357 reads (15%) | catalogued as COSV100106200; called by muse, mutect2, varscan2
- RAPGEF3 | c.1818T>C p.S606= (on ENST00000389212; = p.S564= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99406867; called by muse, mutect2, varscan2
- RYR2 | c.2352C>T p.I784= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as rs573789485, COSV63663931; called by muse, mutect2
- SCAI | c.123C>T p.I41= (on ENST00000336505 / NM_001144877.3; = p.I64= on NM_173690.5) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV60615276, COSV60620010; called by muse, mutect2, varscan2
- SCN11A | c.2937G>A p.Q979= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs1231569540, COSV100182566; called by muse, mutect2, varscan2
- SCN3A | c.585C>T p.F195= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs1324453645, COSV51820377; called by muse, mutect2, varscan2
- SELENOP | c.33C>T p.L11= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1416206076, COSV101539878; called by muse, mutect2, varscan2
- SELP | c.2142G>A p.A714= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs138760541; called by muse, mutect2, varscan2
- SFTPA1 | c.132G>A p.R44= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV64867528; called by muse, mutect2
- SI | c.2640C>T p.I880= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV52281467, COSV52302480; called by muse, mutect2, varscan2
- SLC22A13 | c.1245C>T p.P415= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs779792115, COSV100314683; called by muse, varscan2
- SLC38A10 | c.1917A>T p.T639= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs1341921459, COSV99917918; called by muse, mutect2, varscan2
- SLC38A4 | c.156C>T p.F52= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV56967391; called by muse, mutect2, varscan2
- SLC44A5 | c.450G>A p.K150= | Silent (SNP) | VAF 53/214 reads (25%) | catalogued as rs766643767, COSV100902676; called by muse, mutect2, varscan2
- SLC46A2 | c.1416C>T p.I472= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV100953517; called by muse, mutect2, varscan2
- SLC52A2 | c.1275C>T p.P425= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100096077; called by muse, mutect2, varscan2
- SLC6A18 | c.570C>T p.S190= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV99722685; called by muse, mutect2
- SLC9A8 | c.1278G>A p.R426= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1214759120, COSV100846324; called by mutect2, varscan2
- SLIT3 | c.3102G>A p.V1034= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100269930; called by muse, mutect2, varscan2
- SORL1 | c.2415C>T p.S805= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs532535284, COSV52748908; called by muse, mutect2, varscan2
- SPARC | c.81G>A p.E27= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV99163885; called by muse, mutect2, varscan2
- ST8SIA5 | c.972C>T p.F324= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV100164595; called by muse, mutect2, varscan2
- ST8SIA5 | c.339C>T p.A113= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100164980; called by muse, mutect2, varscan2
- TAL1 | c.459G>A p.G153= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99596401; called by muse, mutect2, varscan2
- THBS4 | c.321G>A p.G107= | Silent (SNP) | VAF 66/250 reads (26%) | catalogued as rs770357704, COSV100644158; called by muse, mutect2, varscan2
- TRANK1 | c.2622C>T p.I874= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs866510996, COSV57139793; called by muse, mutect2, varscan2
- TRBV27 | c.15C>T p.L5= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TTC6 | c.1197C>T p.S399= (on ENST00000267368; = p.S1765= on NM_001310135.3) | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV99942282; called by muse, mutect2, varscan2
- UQCR10 | c.93C>T p.F31= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100340839; called by muse, mutect2, varscan2
- USP26 | c.2736G>A p.K912= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs200476998, COSV100896764; called by muse, mutect2, varscan2
- USP43 | c.795C>T p.F265= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as COSV53306053; called by muse, mutect2, varscan2
- VIL1 | c.1230G>A p.L410= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV99945873; called by muse, mutect2, varscan2
- ZBED6CL | c.33C>T p.A11= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV100550635; called by muse, mutect2, varscan2
- ZFHX3 | c.393G>A p.G131= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99214706; called by muse, mutect2, varscan2
- ZMYM6 | c.2265C>T p.I755= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100593333; called by mutect2, varscan2
- ZNF142 | c.3165C>T p.S1055= (on ENST00000411696 / NM_001379660.1; = p.S855= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs764679397, COSV101377002; called by muse, mutect2, varscan2
- ZNF391 | c.681G>A p.G227= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV99772819; called by muse, mutect2, varscan2
- MIR525 | n.62C>T | RNA (SNP) | VAF 16/104 reads (15%) | catalogued as rs959657314; called by muse, mutect2, varscan2
- MOCS1 | c.124-19C>T | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs748716557, COSV100418840; called by muse, mutect2, varscan2
- OSGIN1 | n.884C>T | RNA (SNP) | VAF 7/54 reads (13%) | catalogued as rs773034598, COSV59676501; called by muse, mutect2, varscan2
- PAK4 | c.-1C>T | 5'UTR (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100426608; called by muse, mutect2, varscan2
- PLB1 | c.2321+263C>T | Intron (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100215484; called by muse, mutect2, varscan2
- SCN3A | c.603-140G>A | Intron (SNP) | VAF 25/95 reads (26%) | catalogued as rs77258062, COSV51802803; called by muse, mutect2, varscan2
- SSPOP | n.1804G>A | RNA (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100023010; called by muse, mutect2, varscan2
- SYT1 | c.929-24761C>G | Intron (SNP) | VAF 8/68 reads (12%) | catalogued as COSV54038262, COSV99697447; called by muse, mutect2
- UVSSA | c.*9198G>A | 3'UTR (SNP) | VAF 87/405 reads (21%) | catalogued as rs770931098, COSV100246330; called by muse, mutect2, varscan2
- XIST | n.7806C>T | RNA (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
